Somatic mutation profile of tumor specimen HCM-BROD-0685-C71-01A (aliquot HCM-BROD-0685-C71-01A-01D-A85C-36) from HCMI case HCM-BROD-0685-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.8 years (25,506 days).
Specimen HCM-BROD-0685-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e15cb36-bcc0-403c-a5ba-83d6d0550a1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0685-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0685-C71-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28e2d2d7-9c56-4112-9950-288359d8ff76

The open-access MAF lists 60 somatic variants for this specimen: 37 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 20, Nonsense Mutation 5, 3'UTR 3, Nonstop Mutation 1, In Frame Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 70/184 reads (38%) | hotspot (GDC flag); catalogued as rs121913303, CM961229, COSV57297124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 143/303 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APOBEC3B | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 82/519 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as rs770453697; called by muse, varscan2
- DDC | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 96/478 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV63565075; called by muse, mutect2, varscan2
- DYNC1I1 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 73/323 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.629); catalogued as rs369627655; called by muse, mutect2, varscan2
- GPT | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 162/613 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs530505425; called by muse, mutect2, varscan2
- GRM3 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 69/360 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64467183, COSV64474717; called by muse, mutect2, varscan2
- HLA-DRA | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 95/348 reads (27%) | catalogued as rs754420534, COSV66623242; called by muse, mutect2, varscan2
- HRNR | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 102/416 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs201404604, COSV64255160; called by muse, varscan2
- HUNK | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 88/397 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776863029; called by muse, mutect2, varscan2
- MXRA5 | c.5767C>T p.R1923* | Nonsense Mutation (SNP) | VAF 118/252 reads (47%) | catalogued as rs527784574, COSV54222197; called by muse, mutect2, varscan2
- NIPBL | c.7220G>T p.R2407L | Missense Mutation (SNP) | VAF 80/274 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM148618, COSV56952574; called by muse, mutect2, varscan2
- NRK | c.2418C>T p.S806= | Splice Region (SNP) | VAF 78/137 reads (57%) | catalogued as rs774915551; called by muse, mutect2, varscan2
- OR14I1 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 88/408 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs766507577, COSV100700498; called by muse, varscan2
- PGK2 | c.971A>G p.H324R | Missense Mutation (SNP) | VAF 105/328 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV59163494; called by muse, varscan2
- PTEN | c.16A>G p.K6E | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as CM142085, COSV64291830; called by muse, mutect2, varscan2
- RHEX | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 79/316 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs531574406, COSV58980514; called by muse, mutect2, varscan2
- RHOV | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 78/326 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1239281442; called by muse, mutect2, varscan2
- RNF169 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 121/529 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV55132637; called by muse, mutect2, varscan2
- SAMD1 | c.931+1G>A p.X311_splice | Splice Site (SNP) | VAF 90/388 reads (23%) | catalogued as rs1170878325; called by muse, mutect2, varscan2
- SIGLEC6 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 31/574 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.025); catalogued as rs757685540, COSV58433672; called by muse, mutect2
- TMEM63C | c.2285G>A p.R762K | Missense Mutation (SNP) | VAF 47/415 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as rs1192776666; called by muse, mutect2, varscan2
- TOPAZ1 | c.3811C>T p.R1271* | Nonsense Mutation (SNP) | VAF 34/158 reads (22%) | catalogued as rs752812035; called by muse, mutect2, varscan2
- CP | c.311A>C p.K104T | Missense Mutation (SNP) | VAF 73/273 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DTX3L | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 111/271 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IZUMO3 | c.421G>T p.G141C (on ENST00000543880 / NM_001365008.2; = p.G135C on NM_001271706.1) | Missense Mutation (SNP) | VAF 74/261 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- KBTBD6 | c.637A>G p.T213A | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF20A | c.796_798del p.S266del | In Frame Del (DEL) | VAF 53/269 reads (20%) | called by pindel, varscan2
- MMRN1 | c.3685T>A p.*1229Kext*43 | Nonstop Mutation (SNP) | VAF 53/182 reads (29%) | called by muse, varscan2
- MUC17 | c.6282C>G p.I2094M | Missense Mutation (SNP) | VAF 76/422 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.242); called by muse, varscan2
- OR52E5 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 87/321 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- OR5AC2 | c.434A>T p.Q145L | Missense Mutation (SNP) | VAF 93/268 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.309); called by muse, varscan2
- PMS2 | c.756T>A p.C252* | Nonsense Mutation (SNP) | VAF 90/375 reads (24%) | called by muse, mutect2, varscan2
- RPAP1 | c.2522T>C p.L841P | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, varscan2
- SEMA3E | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 57/327 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, varscan2
- TCHH | c.2361G>T p.R787S | Missense Mutation (SNP) | VAF 150/610 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.665); called by muse, varscan2
- TRIM15 | c.727A>T p.S243C | Missense Mutation (SNP) | VAF 110/363 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- A1CF | c.1773T>C p.Y591= (on ENST00000373993 / NM_138932.2; = p.Y583= on NM_014576.4) | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as rs1205244851; called by muse, mutect2, varscan2
- ATAD3C | c.501G>A p.R167= | Silent (SNP) | VAF 74/349 reads (21%) | catalogued as rs774656765; called by muse, mutect2, varscan2
- CUL4B | c.1614G>A p.E538= | Silent (SNP) | VAF 84/144 reads (58%) | called by muse, mutect2, varscan2
- EIF2B4 | c.463C>T p.L155= (on ENST00000347454 / NM_001034116.2; = p.L154= on NM_015636.3) | Silent (SNP) | VAF 89/294 reads (30%) | called by muse, mutect2, varscan2
- EP400 | c.8937G>A p.P2979= | Silent (SNP) | VAF 153/492 reads (31%) | catalogued as rs748552218; called by muse, mutect2, varscan2
- HRNR | c.2001C>T p.S667= | Silent (SNP) | VAF 134/572 reads (23%) | catalogued as rs374849852; called by muse, varscan2
- ITGA4 | c.1278G>A p.S426= | Silent (SNP) | VAF 65/234 reads (28%) | catalogued as rs201581651, COSV52001707, COSV99275884; called by muse, mutect2, varscan2
- MSLN | c.1050C>T p.D350= | Silent (SNP) | VAF 86/379 reads (23%) | catalogued as rs772391015; called by muse, mutect2, varscan2
- NMUR2 | c.459C>T p.R153= | Silent (SNP) | VAF 109/401 reads (27%) | catalogued as rs1004624182, COSV99677400; called by muse, varscan2
- NPHS1 | c.2013C>T p.S671= | Silent (SNP) | VAF 151/574 reads (26%) | catalogued as rs775801945, COSV62287390; called by muse, mutect2, varscan2
- PCDHGA7 | c.1338C>T p.N446= | Silent (SNP) | VAF 98/378 reads (26%) | catalogued as COSV53916861; called by muse, varscan2
- PKLR | c.822C>T p.F274= | Silent (SNP) | VAF 202/655 reads (31%) | catalogued as rs1233630203; called by muse, varscan2
- PLXNA2 | c.4683C>T p.A1561= | Silent (SNP) | VAF 82/335 reads (24%) | called by muse, mutect2, varscan2
- PRSS45P | c.741C>A p.L247= | Silent (SNP) | VAF 94/444 reads (21%) | catalogued as COSV101373924; called by muse, mutect2, varscan2
- REELD1 | c.747A>G p.P249= | Silent (SNP) | VAF 105/396 reads (27%) | called by muse, mutect2, varscan2
- RSPH4A | c.1683C>T p.N561= | Silent (SNP) | VAF 59/229 reads (26%) | catalogued as rs1451660000; called by muse, mutect2, varscan2
- SCN5A | c.5373C>T p.F1791= (on ENST00000333535 / NM_198056.3; = p.F1790= on NM_000335.5) | Silent (SNP) | VAF 62/259 reads (24%) | catalogued as rs372380415; ClinVar: likely benign; called by muse, varscan2
- SEMA6B | c.300C>T p.Y100= | Silent (SNP) | VAF 52/572 reads (9%) | called by muse, mutect2
- SEPTIN5 | c.855C>T p.N285= | Silent (SNP) | VAF 81/263 reads (31%) | called by muse, mutect2, varscan2
- SSC5D | c.1137C>T p.A379= | Silent (SNP) | VAF 136/570 reads (24%) | called by muse, mutect2, varscan2
- DEFB110 | c.*1C>T | 3'UTR (SNP) | VAF 58/201 reads (29%) | catalogued as rs761064329, COSV100953811; called by muse, mutect2, varscan2
- PEG10 | c.*1100G>A | 3'UTR (SNP) | VAF 78/421 reads (19%) | called by muse, varscan2
- POU2F2 | c.*238G>A | 3'UTR (SNP) | VAF 102/411 reads (25%) | catalogued as rs1456130043; called by muse, mutect2, varscan2
